Somatic mutation profile of tumor specimen TCGA-FG-A60J-01A (aliquot TCGA-FG-A60J-01A-11D-A289-08) from TCGA case TCGA-FG-A60J, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 47.5 years (17,339 days).
Specimen TCGA-FG-A60J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee04e68b-1416-4ab7-9abd-690efc172231.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A60J-10A (Blood Derived Normal), aliquot TCGA-FG-A60J-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e687be03-50cc-421c-8427-94e4ee1e2b6c

The open-access MAF lists 41 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Nonsense Mutation 2, Splice Site 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.783-2A>C p.X261_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); catalogued as COSV52818160, COSV52984227, COSV53085853; called by muse, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 45/84 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABR | c.1996C>T p.Q666* (on ENST00000302538 / NM_021962.5; = p.Q629* on NM_001092.5) | Nonsense Mutation (SNP) | VAF 54/133 reads (41%) | catalogued as COSV52149268; called by muse, mutect2, varscan2
- AC005324.2 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as COSV60887701; called by muse, mutect2, varscan2
- ARHGAP36 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV52269757; called by muse, mutect2
- CASP1 | c.1143T>G p.D381E (on ENST00000436863 / NM_033292.4; = p.D360E on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52830467; called by muse, mutect2
- CHRNA5 | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55139655; called by muse, mutect2, varscan2
- CPZ | c.394G>A p.A132T (on ENST00000360986 / NM_001014447.3; = p.A121T on NM_003652.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as rs777352854, COSV59922086; called by muse, mutect2, varscan2
- CSTF2 | c.299A>T p.E100V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV63376425; called by muse, mutect2, varscan2
- DOCK11 | c.4048T>A p.S1350T | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV52244231; called by muse, mutect2, varscan2
- DRP2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs754934754, COSV65811183; called by muse, mutect2, varscan2
- GABRA3 | c.1249T>A p.S417T | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.131); catalogued as COSV64802706; called by muse, mutect2
- HOXA7 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV54218429; called by muse, mutect2, varscan2
- HS3ST3A1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs750522076, COSV52372487; called by muse, mutect2, varscan2
- LATS2 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1421513550, COSV66878098; called by muse, mutect2, varscan2
- MPPED1 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV68838833; called by muse, mutect2, varscan2
- NAA10 | c.532A>G p.N178D | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV63133377; called by muse, mutect2, varscan2
- OGT | c.1320+1G>T p.X440_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as COSV65481993; called by muse, mutect2, varscan2
- OR2M3 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 23/327 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV71759199; called by muse, mutect2
- OR5I1 | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV56888306; called by muse, mutect2, varscan2
- PIK3R4 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV63242712; called by muse, mutect2, varscan2
- RTL5 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV65453893; called by muse, mutect2, varscan2
- SAXO1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1465148500, COSV65871116; called by muse, mutect2, varscan2
- SERPINA7 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59666685; called by muse, mutect2, varscan2
- SH2D1B | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs564269887, COSV63392540; called by muse, mutect2, varscan2
- SRRM4 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs1490798590, COSV57422148, COSV99938440; called by muse, mutect2, varscan2
- SSTR3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as COSV60729318; called by muse, mutect2, varscan2
- SYNE2 | c.19447T>C p.S6483P | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV100646853, COSV59961076; called by muse, mutect2, varscan2
- TAZ | c.122A>T p.H41L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as COSV50010809; called by muse, mutect2
- TMEM155 | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100530108, COSV61795174; called by muse, mutect2, varscan2
- WDR93 | c.798T>C p.D266= | Splice Region (SNP) | VAF 3/49 reads (6%) | catalogued as COSV99175713; called by muse, mutect2
- XKR4 | c.1777T>C p.S593P | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV59330003; called by muse, mutect2, varscan2
- ADGRG4 | c.2604G>C p.L868= | Silent (SNP) | VAF 23/290 reads (8%) | catalogued as COSV54962578; called by muse, mutect2
- GRIPAP1 | c.2319G>C p.L773= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV54415264; called by muse, mutect2, varscan2
- LETM2 | c.1194G>A p.P398= (on ENST00000379957 / NM_001286819.2; = p.P303= on NM_144652.3) | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs766963616, COSV52686350; called by muse, mutect2, varscan2
- NEMF | c.1968T>G p.L656= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV53593771; called by muse, mutect2, varscan2
- SEC61A1 | c.993C>T p.G331= | Silent (SNP) | VAF 58/164 reads (35%) | catalogued as COSV54578212; called by muse, mutect2, varscan2
- TLL2 | c.2844C>T p.Y948= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs770297618, COSV63574419; called by muse, mutect2, varscan2
- ZNF81 | c.699T>C p.Y233= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs782478712, COSV58577509; called by muse, mutect2, varscan2
- LRRC55 | c.-50A>G | 5'UTR (SNP) | VAF 11/73 reads (15%) | catalogued as rs1185129656, COSV73006498; called by muse, mutect2, varscan2
